Surgical pathology report (de-identified scan), TCGA case TCGA-EM-A3OB, project TCGA-THCA (Thyroid Carcinoma), tissue source site University Health Network, specimen TCGA-EM-A3OB-01A (Primary Tumor).

[page 1 of 2]
LABORATORY MEDICINE PROGRAM

Surgical Pathology Consultation Report

DOB: [Redacted]
Gender: [Redacted]
HCN: [Redacted]
Ordering: [Redacted]
Copy: [Redacted]

Service: [Redacted]
Visit #: [Redacted]
Location: [Redacted]
Facility: [Redacted]

Accession #: [Redacted]
Collected: [Redacted]
Received: [Redacted]
Reported: [Redacted]

Specimen(s) Received

1. Lymph-Node: left paratracheal
2. Thyroid: Total thyroid stitch mark left upper

Diagnosis

1. No pathological diagnosis: Lymph node, 1, left paratracheal, excisional biopsy.
2. Papillary carcinoma, follicular variant 2.2 cm, isthmus; mild follicular nodular disease and nonspecific chronic thyroiditis:
Thyroid
No pathological diagnosis: Lymph nodes, 3, isthmus
No pathological diagnosis: Parathyroid, right perithyroidal
No pathological diagnosis: Parathyroid, left intrathyroidal
-Total thyroidectomy specimen.

ICD-O-3

carcinoma, papillary, follicular variant. 8340/3
Site: thyroid, NOS 073.9
W
2/5/12

Synoptic Data

Procedure:	Total thyroidectomy
Received:	Fresh
Specimen Integrity:	Intact
Specimen Size:	Right lobe:
	5.4 cm
	2.3 cm
	1.4 cm
	Left lobe:
	4.6 cm
	1.8 cm
	1.4 cm
	Isthmus +/- pyramidal lobe:
	5.5 cm
	1.8 cm
	1.7 cm
Specimen Weight:	21.4 g
Tumor Focality:	Unifocal
----- DOMINANT TUMOR -----	
Tumor Laterality:	Isthmus
Tumor Size:	Greatest dimension: 2.2cm
	Additional dimension: 1.6 cm

[page 2 of 2]
Surgical Pathology Consultation Report

Histologic Type:	Additional dimension: 1.2 cm Papillary carcinoma, follicular variant Follicular architecture Classical cytomorphology
Histologic Grade:	Not applicable
Margins:	Margins uninvolved by carcinoma
Tumor Capsule:	Partially encapsulated
Tumor Capsular Invasion:	Not identified
Lymph-Vascular Invasion:	Not identified
Perineural Invasion:	Not identified
Extrathyroidal Extension:	Not identified
TNM Descriptors:	Not applicable
Primary Tumor (pT):	pT2: Tumor more than 2 cm, but not more than 4 cm, limited to thyroid
Regional Lymph Nodes (pN):	pN0: No regional lymph node metastasis Number of regional lymph nodes examined: 4 Number of regional lymph nodes involved: 0
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	Adenomatoid nodule(s) or Nodular follicular disease Thyroiditis, focal (nonspecific) Parathyroid gland(s), within normal limits

*Pathologic Staging is based on AJCC/UICC TNM, 7th Edition

Electronically verified by:

Gross Description

1. The specimen container is labeled with the patient's name and as "Lymph Node: Left paratracheal" consists of a fragment of yellow tissue measuring 0.5 x 0.2 x 0.2 cm received in 10% buffered formalin.

1A- submitted in toto.

2. The specimen labeled with the patient's name and as "Thyroid: Total thyroid stitch mark left upper" consists of a thyroid gland that is oriented with a stitch and weighs 21.4 g. The right lobe measures 5.4 cm SI x 2.3 cm ML x 1.4 cm AP, the left lobe measures 4.6 cm SI x 1.8 cm ML x 1.4 cm AP and the isthmus measures 5.5 cm SI x 1.8 cm ML x 1.7 cm AP. The external surfaces have fibrous adhesions and are painted with Silver nitrate. No parathyroid glands and lymph nodes are identified grossly. The isthmus contains a well delineated nodule that measures 2.2 cm SI x 1.2 cm ML x 1.6 cm AP. The remainder of the thyroid tissue is grossly unremarkable. Sections of isthmus nodule and normal tissue are stored frozen. The remainder of the specimen is submitted as follows:

2A-G right lobe, superior to inferior

2H-L isthmus

2M-R left lobe, superior to inferior

Source: NCI Genomic Data Commons file d0d85091-a90a-4254-9bf3-95b51b93225b (TCGA-EM-A3OB.E32ED26A-731B-4D14-A5CB-6C87A5D876DA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).